Somatic mutation profile of tumor specimen C3N-00221-06 (aliquot CPT0111150015) from CPTAC case C3N-00221, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 78.6 years (28,711 days).
Specimen C3N-00221-06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2a253a1-4ac2-4cfa-a372-a98a22eeda59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00221-75 (Blood Derived Normal), aliquot CPT0111280005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b8f58e-cf3f-449e-a3f7-8e3f490e672c

The open-access MAF lists 380 somatic variants for this specimen: 273 protein-altering or splice-affecting, 62 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 62, Frame Shift Del 16, Intron 15, RNA 11, 3'UTR 9, Nonsense Mutation 8, 5'UTR 7, Splice Region 4, Splice Site 3, 5'Flank 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>T p.R1446L | Missense Mutation (SNP) | VAF 93/234 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 234/366 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSF3 | c.1444T>C p.Y482H | Missense Mutation (SNP) | VAF 134/191 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as rs776369896; called by muse, mutect2, varscan2
- ACSM2A | c.240G>T p.M80I (on ENST00000219054; = p.M1? on NM_001308169.2) | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1349662791, COSV54587055; called by muse, mutect2, varscan2
- ADAMTS3 | c.3481G>C p.A1161P | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs765945637; called by muse, mutect2, varscan2
- ADCY8 | c.2975C>A p.A992E | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV53896037, COSV53906569; called by muse, varscan2
- ADGRG3 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 124/306 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.217); catalogued as rs777986530; called by muse, mutect2, varscan2
- ALX1 | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV57492227; called by muse, mutect2, varscan2
- ARHGAP12 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60963970; called by muse, mutect2, varscan2
- BOP1 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1376741082; called by muse, mutect2, varscan2
- BRINP2 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 170/749 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV100838014, COSV64176192; called by muse, mutect2, varscan2
- CACNA1E | c.4334C>A p.A1445E | Missense Mutation (SNP) | VAF 154/269 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62387510; called by muse, mutect2, varscan2
- CBLIF | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 101/447 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs749528399; called by muse, mutect2, varscan2
- CDC14A | c.1345A>G p.K449E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.165); catalogued as rs752941272, COSV60562288; called by muse, mutect2, varscan2
- CNBD2 | c.1630C>T p.R544C (on ENST00000373973 / NM_001365709.1; = p.R540C on NM_080834.4) | Missense Mutation (SNP) | VAF 111/379 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs757298997, COSV62586275; called by muse, mutect2, varscan2
- CNGA4 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs779069159, COSV66005702; called by muse, mutect2
- CRB1 | c.3079C>A p.Q1027K | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.987); catalogued as COSV66328561; called by muse, mutect2, varscan2
- CUL3 | c.2267del p.R756Qfs*12 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | catalogued as COSV52361183, COSV52363524; called by mutect2, pindel, varscan2
- CXorf21 | c.794C>A p.S265* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | catalogued as COSV100973355; called by muse, mutect2, varscan2
- CYP46A1 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs757381529, COSV99952405; called by muse, mutect2
- DACH2 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs963035467, COSV64175398; called by muse, mutect2, varscan2
- DAZL | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99167504; called by muse, mutect2, varscan2
- DCDC1 | c.3527G>A p.S1176N (on ENST00000597505 / NM_001367979.1; = p.S283N on NM_020869.3) | Missense Mutation (SNP) | VAF 130/303 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV60305079; called by muse, mutect2, varscan2
- DCP1B | c.1711G>A p.V571M | Missense Mutation (SNP) | VAF 102/401 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs140288898; called by muse, mutect2, varscan2
- EYS | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.624); catalogued as COSV60977268, COSV60982026, COSV61002672; called by muse, mutect2, varscan2
- FBXO4 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779351405; called by muse, mutect2, varscan2
- FCRL2 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 200/410 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); catalogued as rs780187150; called by muse, mutect2, varscan2
- FGF5 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 93/137 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as rs1181309232; called by muse, mutect2, varscan2
- FGFR4 | c.1949G>T p.R650L | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172824038, COSV52801476; called by muse, mutect2, varscan2
- FITM1 | c.629A>T p.H210L | Missense Mutation (SNP) | VAF 133/431 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1377279878; called by muse, mutect2, varscan2
- FMN1 | c.1979G>A p.C660Y | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious, low confidence (0); catalogued as rs1440867244; called by muse, mutect2, varscan2
- HLTF | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV59500627; called by muse, mutect2, varscan2
- IGHD4-17 | c.10T>A p.*4Rext*? | Nonstop Mutation (SNP) | VAF 101/314 reads (32%) | catalogued as rs1198593351; called by muse, mutect2, varscan2
- IGHV4-39 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 148/788 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.716); catalogued as rs191739990; called by muse, mutect2, varscan2
- IL21R | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752484051, COSV61969533, COSV61971718; called by muse, mutect2, varscan2
- ITK | c.1229T>C p.M410T | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs776824188; called by muse, mutect2, varscan2
- KCTD7 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 92/377 reads (24%) | catalogued as COSV51877186; called by muse, mutect2, varscan2
- KCTD7 | c.562C>G p.P188A (on ENST00000275532; = p.P201R on NM_153033.5) | Missense Mutation (SNP) | VAF 108/193 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.737); catalogued as rs774050685; called by muse, mutect2, varscan2
- KIF2B | c.1576T>A p.S526T | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52128033; called by muse, mutect2, varscan2
- KIF4B | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70531201; called by muse, mutect2, varscan2
- KIF7 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1214331197; called by muse, mutect2, varscan2
- KIFC2 | c.811-5C>T | Splice Region (SNP) | VAF 107/230 reads (47%) | catalogued as rs750829843; called by muse, mutect2, varscan2
- KSR2 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs749908572; called by muse, mutect2, varscan2
- LRP1 | c.12286G>T p.D4096Y | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54529519; called by muse, mutect2, varscan2
- LRRTM4 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV69140695; called by muse, mutect2, varscan2
- MNS1 | c.100G>T p.V34F | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1473594322; called by muse, mutect2, varscan2
- MYH15 | c.2789G>A p.R930K | Missense Mutation (SNP) | VAF 118/193 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56311966; called by muse, mutect2, varscan2
- MYH4 | c.4228G>C p.A1410P | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55124317; called by muse, mutect2, varscan2
- MYH4 | c.2921C>A p.A974D | Missense Mutation (SNP) | VAF 89/158 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1050159971; called by muse, mutect2, varscan2
- NAP1L1 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV99674179; called by muse, mutect2, varscan2
- NCCRP1 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 304/801 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1025745434; called by muse, mutect2, varscan2
- NEDD4 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330280805, COSV71069561; called by muse, mutect2, varscan2
- NLRP12 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 193/498 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs147810259; called by muse, mutect2, varscan2
- NPAS3 | c.2061C>A p.S687R (on ENST00000356141 / NM_001164749.2; = p.S655R on NM_022123.3) | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV60823356; called by muse, mutect2, varscan2
- NRXN1 | c.2414A>G p.N805S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753087756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs748372282, COSV68004989, COSV68005183; called by muse, mutect2, varscan2
- NTRK3 | c.2211G>A p.M737I (on ENST00000360948 / NM_001012338.2; = p.M723I on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99051176; called by muse, mutect2, varscan2
- OR2T12 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58775805, COSV58779580; called by muse, mutect2, varscan2
- OR2T12 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 202/598 reads (34%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.513); catalogued as COSV58779826; called by mutect2, varscan2
- OR4N2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60052188; called by muse, mutect2
- OR8J3 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV56884191; called by muse, mutect2, varscan2
- OR9G1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV56448152, COSV56451460; called by muse, varscan2
- OSBPL10 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67344516; called by muse, mutect2, varscan2
- OTOGL | c.1692C>G p.N564K (on ENST00000547103; = p.N555K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV101509532; called by muse, mutect2, varscan2
- PCDHA10 | c.1502G>T p.R501L | Missense Mutation (SNP) | VAF 266/771 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.394); catalogued as rs782300527, COSV56514639; called by muse, mutect2, varscan2
- PCDHA3 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs546101434; called by muse, mutect2, varscan2
- PCNX3 | c.2344G>T p.A782S | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV63135606; called by muse, mutect2, varscan2
- PHC3 | c.2866G>A p.E956K (on ENST00000494943 / NM_001308116.2; = p.E968K on NM_024947.4) | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV72228330; called by muse, mutect2
- PLS3 | c.1727A>G p.N576S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs782721109; called by muse, mutect2, varscan2
- PLXNA4 | c.5013G>T p.K1671N | Missense Mutation (SNP) | VAF 107/1013 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58125289; called by muse, mutect2, varscan2
- PODN | c.281C>A p.A94E (on ENST00000395871; = p.A46E on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 268/409 reads (66%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.045); catalogued as rs779434575, COSV57015223; called by muse, mutect2, varscan2
- POLM | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV54242629; called by muse, mutect2, varscan2
- POTEE | c.325T>A p.C109S | Missense Mutation (SNP) | VAF 244/671 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); catalogued as rs747071414; called by muse, mutect2, varscan2
- RBP3 | c.3451G>A p.A1151T | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782249467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RC3H1 | c.3111del p.K1038Rfs*6 | Frame Shift Del (DEL) | VAF 82/187 reads (44%) | catalogued as COSV51204213; called by mutect2, pindel, varscan2
- RNF135 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 826/1202 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV100104096; called by muse, mutect2, varscan2
- RNF168 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as rs1484807267; called by muse, mutect2, varscan2
- RPTOR | c.3487A>C p.T1163P | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV60805570; called by muse, mutect2, varscan2
- SELPLG | c.248T>A p.V83E | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV57311621; called by muse, mutect2, varscan2
- SHOX | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 232/563 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1414612496, CM125835; called by muse, mutect2, varscan2
- SKIV2L | c.8A>C p.E3A | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as rs557492102; called by muse, mutect2, varscan2
- SLC25A12 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55533064; called by muse, mutect2, varscan2
- SLC4A8 | c.2062G>T p.G688* | Nonsense Mutation (SNP) | VAF 76/187 reads (41%) | catalogued as COSV60647714; called by muse, mutect2, varscan2
- SLC4A8 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60648616; called by muse, mutect2, varscan2
- SLC7A10 | c.927G>T p.K309N | Missense Mutation (SNP) | VAF 131/388 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV53504523; called by muse, mutect2, varscan2
- SOX2 | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 570/2092 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1224015575; called by muse, mutect2, varscan2
- SPATA31D1 | c.3742G>T p.D1248Y | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100782469, COSV61195726; called by muse, mutect2, varscan2
- STOX1 | c.441G>C p.E147D | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV53818007; called by muse, mutect2, varscan2
- TBCD | c.1862C>T p.S621L | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs201176158; called by muse, mutect2, varscan2
- TECPR1 | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs760164335; called by muse, mutect2, varscan2
- TEX15 | c.4502G>T p.C1501F (on ENST00000256246; = p.C1884F on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.055); catalogued as COSV99821022; called by muse, mutect2, varscan2
- TLE3 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV58174713; called by muse, mutect2, varscan2
- TMEM132C | c.2954G>C p.G985A | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as rs1223805238; called by muse, mutect2, varscan2
- TNNT2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201048783, CM106921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF616 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57510562; called by muse, mutect2, varscan2
- ZNF99 | c.2234C>A p.S745Y | Missense Mutation (SNP) | VAF 89/171 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.332); catalogued as COSV101233678; called by muse, mutect2, varscan2
- ZNRF3 | c.1843_1851del p.S615_G617del (on ENST00000544604 / NM_001206998.2; = p.S515_G517del on NM_032173.3) | In Frame Del (DEL) | VAF 24/162 reads (15%) | catalogued as rs747735040; called by mutect2, varscan2
- AADACL2 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACSBG2 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTN2 | c.1436T>A p.V479D | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADCK1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ADGRV1 | c.11618C>A p.T3873N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.17482A>T p.S5828C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- AFDN | c.2391G>T p.W797C | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AFF3 | c.725A>G p.D242G | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AKAP12 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AKAP6 | c.4352del p.P1451Lfs*32 | Frame Shift Del (DEL) | VAF 36/91 reads (40%) | called by mutect2, pindel, varscan2
- ANK2 | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD30B | c.3605C>G p.A1202G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- APBA2 | c.2056G>A p.G686R | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF18 | c.392G>A p.G131E (on ENST00000359920 / NM_001130955.2; = p.G27E on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ARPP21 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP4A | c.2242G>T p.A748S | Missense Mutation (SNP) | VAF 145/352 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- BEND2 | c.1027T>A p.Y343N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- C6orf47 | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 117/466 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- CABP7 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- CACNA1E | c.5574del p.A1860Pfs*4 | Frame Shift Del (DEL) | VAF 92/215 reads (43%) | called by mutect2, pindel, varscan2
- CCDC170 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CCDC175 | c.944A>T p.E315V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC74B | c.684-2A>T p.X228_splice | Splice Site (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2
- CCL4L2 | c.235A>C p.K79Q (on ENST00000617405 / NM_001291475.2; = p.G75= on NM_001291471.2) | Missense Mutation (SNP) | VAF 212/1662 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.144); called by mutect2, varscan2
- CD5L | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 445/817 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDK19 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CELA1 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- CEP250 | c.6460del p.R2154Gfs*6 | Frame Shift Del (DEL) | VAF 162/362 reads (45%) | called by mutect2, pindel*, varscan2
- CEP350 | c.5663A>T p.E1888V | Missense Mutation (SNP) | VAF 125/239 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CHRNB4 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.088); called by muse, mutect2
- CHTF18 | c.997C>G p.R333G | Missense Mutation (SNP) | VAF 299/601 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CLRN1 | c.341T>C p.V114A (on ENST00000327047 / NM_174878.3; = p.V38A on NM_052995.2) | Missense Mutation (SNP) | VAF 119/468 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLTCL1 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CLVS2 | c.707T>A p.L236Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CNTNAP5 | c.2273C>A p.P758H | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- COL22A1 | c.4413G>T p.E1471D | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- COL6A1 | c.2120T>A p.L707Q | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ8B | c.798G>T p.A266= | Splice Region (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- COX7B2 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CSMD2 | c.7424_7440del p.L2475Rfs*55 | Frame Shift Del (DEL) | VAF 68/129 reads (53%) | called by mutect2, pindel, varscan2
- CSMD3 | c.6032G>T p.G2011V (on ENST00000297405 / NM_001363185.1; = p.G1907V on NM_052900.3) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUL1 | c.1618C>A p.L540M | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL4A | c.783C>A p.N261K (on ENST00000375440 / NM_001008895.4; = p.N161K on NM_003589.3) | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDC | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 290/720 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- DLL4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 34/618 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.029); called by muse, mutect2
- DMD | c.7824G>T p.E2608D | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DMRTB1 | c.1001A>T p.Q334L | Missense Mutation (SNP) | VAF 119/191 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DRC7 | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- EP400 | c.2294A>G p.K765R | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- EPS15 | c.1918+1del p.X640_splice | Splice Site (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- ESPN | c.1156A>T p.S386C | Missense Mutation (SNP) | VAF 348/523 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- EYS | c.2532del p.Q844Hfs*24 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- F13B | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FAM135B | c.2067G>T p.E689D | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM174B | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FAT1 | c.11404G>T p.G3802* | Nonsense Mutation (SNP) | VAF 67/108 reads (62%) | called by muse, mutect2, varscan2
- FAT4 | c.6412A>G p.T2138A | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FGG | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- FO393400.1 | c.81_82del p.Q28Afs*15 | Frame Shift Del (DEL) | VAF 118/378 reads (31%) | called by pindel, varscan2
- FOXD4L5 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); called by mutect2, varscan2
- FOXO3 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 126/477 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- FPGT-TNNI3K | c.2099A>G p.H700R | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FSIP2 | c.12199_12201del p.N4067del | In Frame Del (DEL) | VAF 13/32 reads (41%) | called by pindel, varscan2*
- GIPC2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 171/390 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GP5 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.024); called by muse, mutect2
- GTF3C5 | c.1553A>C p.Y518S | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H3C8 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 116/428 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HCN1 | c.2315A>G p.Q772R | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HDHD2 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HEATR5B | c.5666T>A p.F1889Y | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- HLX | c.1351T>A p.C451S | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-45 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 115/288 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGKV1D-43 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 90/288 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, varscan2
- IGLC2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 121/1546 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2
- IQCG | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 32/546 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2
- IRAK2 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 116/341 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ITGA8 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KATNIP | c.2666G>T p.R889L | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KCNT1 | c.1152C>A p.Y384* (on ENST00000488444; = p.Y403* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 58/155 reads (37%) | called by muse, mutect2, varscan2
- KIAA1549 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KIF6 | c.658T>G p.S220A | Missense Mutation (SNP) | VAF 135/238 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KIR3DL1 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 220/536 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2
- KLHL20 | c.1345A>G p.R449G | Missense Mutation (SNP) | VAF 197/363 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KRT19 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 110/267 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KRT37 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 124/385 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LIFR | c.258-1G>T p.X86_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- LIPE | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4C | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- LRRCC1 | c.238A>C p.I80L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2
- LRRTM3 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.14084A>T p.E4695V (on ENST00000372915; = p.E2628V on NM_012090.5) | Missense Mutation (SNP) | VAF 141/214 reads (66%) | called by muse, mutect2, varscan2
- MAGEB5 | c.744C>A p.S248R | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K5 | c.1319T>A p.L440Q | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP6D1 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 84/880 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- MAPK1 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MCHR2 | c.865T>A p.Y289N | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MCL1 | c.563A>G p.E188G | Missense Mutation (SNP) | VAF 100/789 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MDGA2 | c.1742T>A p.M581K (on ENST00000399232 / NM_001113498.2; = p.M283K on NM_182830.4) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MED7 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MICAL3 | c.1612del p.V538* | Frame Shift Del (DEL) | VAF 79/277 reads (29%) | called by mutect2, pindel, varscan2
- MROH2A | c.563A>T p.N188I | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- MRTFB | c.263del p.L88Wfs*10 | Frame Shift Del (DEL) | VAF 38/90 reads (42%) | called by mutect2, pindel, varscan2
- MTPAP | c.1382_1383insCCAGGTCCATAAATATTCG p.G463Vfs*14 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, varscan2*
- MUC4 | c.8948C>G p.S2983C | Missense Mutation (SNP) | VAF 418/1812 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); called by muse, varscan2
- MUC6 | c.4154C>A p.A1385D | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2
- NRXN1 | c.3469A>T p.S1157C | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR2M5 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4P4 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.493); called by muse, mutect2
- OR4P4 | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.12); called by muse, mutect2
- OR52E6 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52I1 | c.16T>A p.Y6N | Missense Mutation (SNP) | VAF 137/276 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5AP2 | c.552C>A p.Y184* | Nonsense Mutation (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- OR5D14 | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- OR8H1 | c.746T>G p.I249S | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- OTOA | c.2111G>A p.C704Y (on ENST00000286149; = p.C690Y on NM_144672.4) | Missense Mutation (SNP) | VAF 147/281 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH9 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE8B | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 121/316 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHACTR2 | c.1145G>T p.R382I | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- PHF14 | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PLA2G12B | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHG2 | c.546G>A p.R182= | Splice Region (SNP) | VAF 102/227 reads (45%) | called by muse, mutect2, varscan2
- PLP1 | c.97T>C p.C33R | Missense Mutation (SNP) | VAF 129/162 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POTEF | c.325T>A p.C109S | Missense Mutation (SNP) | VAF 72/674 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); called by muse, varscan2
- PPP4R4 | c.2618C>G p.P873R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- PRDM14 | c.1333del p.D445Tfs*32 | Frame Shift Del (DEL) | VAF 116/264 reads (44%) | called by mutect2, pindel, varscan2
- PTCD3 | c.1726C>A p.L576I | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); called by muse, mutect2
- PTDSS1 | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- QSOX1 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 181/306 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- RABGAP1L | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- RETREG1 | c.669G>A p.L223= (on ENST00000306320 / NM_001034850.2; = p.L82= on NM_019000.4) | Splice Region (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- RNF139 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RNF43 | c.273C>G p.C91W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ROBO2 | c.70G>C p.V24L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1 | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- RSPH10B | c.2573C>A p.P858Q | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); called by mutect2, varscan2
- SART1 | c.860A>C p.D287A | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN7A | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2
- SDK1 | c.2408G>A p.G803E | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SECISBP2 | c.1244C>A p.A415E | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- SEMG1 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SKA2 | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC17A2 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC2A2 | c.1447A>G p.K483E | Missense Mutation (SNP) | VAF 49/580 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2
- SLC5A11 | c.1637C>G p.P546R | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, mutect2
- SNRPN | c.323G>T p.R108M | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPATA19 | c.42dup p.G15Rfs*15 | Frame Shift Ins (INS) | VAF 29/55 reads (53%) | called by mutect2, pindel, varscan2
- SPATA31A6 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 217/314 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- SPTA1 | c.6652G>T p.D2218Y | Missense Mutation (SNP) | VAF 169/310 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SREBF2 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by mutect2, varscan2
- TET2 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TEX13C | c.1621del p.D541Tfs*7 | Frame Shift Del (DEL) | VAF 228/298 reads (77%) | called by mutect2, varscan2
- THSD7B | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132D | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 188/373 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TMEM236 | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 133/586 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOMM34 | c.749G>T p.C250F | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TOPAZ1 | c.1748T>A p.M583K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TRAT1 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRHR | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TRIM58 | c.491T>A p.V164E | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM7 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRPC4AP | c.1205del p.R402Lfs*9 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- UNC80 | c.701A>T p.K234M | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC80 | c.2011_2012insATGACATCA p.R671delinsHDIS | In Frame Ins (INS) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- URB1 | c.3497del p.Q1166Rfs*16 | Frame Shift Del (DEL) | VAF 76/246 reads (31%) | called by mutect2, varscan2
- URB1 | c.3496del p.Q1166Rfs*16 | Frame Shift Del (DEL) | VAF 66/290 reads (23%) | called by mutect2*, pindel, varscan2*
- VWA5A | c.1418G>C p.W473S | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- WDFY3 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 29/40 reads (73%) | called by muse, mutect2, varscan2
- WSB1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBBX | c.1028del p.P343Hfs*37 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.2834G>A p.C945Y | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF33B | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF518A | c.3116dup p.S1039Rfs*2 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- ZNF675 | c.1668A>T p.K556N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- ZNF729 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 162/336 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZSCAN1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAMTS12 | c.4050C>A p.A1350= | Silent (SNP) | VAF 93/292 reads (32%) | called by muse, mutect2, varscan2
- AGFG1 | c.79C>A p.R27= | Silent (SNP) | VAF 17/476 reads (4%) | catalogued as COSV100028316; called by muse, mutect2
- ALKBH4 | c.207C>T p.P69= | Silent (SNP) | VAF 67/163 reads (41%) | catalogued as COSV52962408; called by muse, mutect2, varscan2
- AMY2A | c.570G>C p.V190= | Silent (SNP) | VAF 60/257 reads (23%) | called by muse, varscan2
- ANKRD31 | c.1482T>C p.Y494= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs201635783; called by muse, mutect2, varscan2
- ANXA9 | c.33C>T p.S11= | Silent (SNP) | VAF 149/305 reads (49%) | catalogued as COSV64485748; called by muse, mutect2, varscan2
- ASCC1 | c.507C>T p.L169= (on ENST00000342444 / NM_001369085.1; = p.L141= on NM_001198798.2 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 58/164 reads (35%) | called by muse, mutect2, varscan2
- ASMTL | c.1122C>T p.H374= | Silent (SNP) | VAF 75/275 reads (27%) | catalogued as rs371878864; called by muse, mutect2, varscan2
- BTN2A1 | c.1275G>A p.E425= | Silent (SNP) | VAF 33/326 reads (10%) | catalogued as rs779754802, COSV57002785; called by muse, mutect2, varscan2
- C8orf74 | c.546G>T p.V182= | Silent (SNP) | VAF 71/132 reads (54%) | called by muse, mutect2, varscan2
- CCDC175 | c.66C>T p.V22= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs546409403; called by muse, mutect2
- CCDC39 | c.1716A>G p.R572= | Silent (SNP) | VAF 28/222 reads (13%) | catalogued as rs375290163; called by muse, mutect2, varscan2
- DCC | c.828C>A p.G276= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as COSV100499966, COSV59108704; called by muse, mutect2, varscan2
- DPP6 | c.1201C>A p.R401= (on ENST00000377770 / NM_001364500.2; = p.R339= on NM_001936.5) | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as COSV100127017, COSV100127633; called by muse, mutect2, varscan2
- DRD5 | c.762G>T p.V254= | Silent (SNP) | VAF 46/83 reads (55%) | called by muse, mutect2, varscan2
- DTX1 | c.1173T>C p.N391= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as rs776026102; called by muse, mutect2, varscan2
- FAM189A1 | c.144A>T p.A48= | Silent (SNP) | VAF 79/374 reads (21%) | called by muse, mutect2, varscan2
- FAT4 | c.10227C>T p.N3409= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as rs368992969; ClinVar: likely benign; called by muse, mutect2, varscan2
- FFAR2 | c.798C>T p.A266= | Silent (SNP) | VAF 229/654 reads (35%) | catalogued as COSV99875957; called by muse, mutect2, varscan2
- GRIK5 | c.2361G>T p.R787= | Silent (SNP) | VAF 71/196 reads (36%) | called by muse, mutect2, varscan2
- HIPK3 | c.1593A>G p.L531= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1289753281; called by muse, mutect2, varscan2
- HS3ST4 | c.828C>A p.S276= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as COSV58803812; called by muse, mutect2, varscan2
- IFIH1 | c.2451C>A p.V817= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- IGHV3-38 | c.204A>T p.S68= | Silent (SNP) | VAF 326/543 reads (60%) | called by muse, mutect2, varscan2
- ITPR1 | c.5106T>G p.A1702= (on ENST00000354582; = p.A1696= on NM_001168272.2) | Silent (SNP) | VAF 36/61 reads (59%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.255G>A p.Q85= | Silent (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- LRRC4C | c.393C>A p.L131= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV53438790; called by muse, mutect2, varscan2
- LRTM2 | c.726C>A p.V242= | Silent (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- LSM10 | c.312G>A p.V104= | Silent (SNP) | VAF 124/173 reads (72%) | called by muse, mutect2, varscan2
- MAPK4 | c.1302G>A p.S434= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs1156555800, COSV101245184; called by muse, mutect2, varscan2
- MRC1 | c.2961A>T p.I987= | Silent (SNP) | VAF 108/201 reads (54%) | called by muse, mutect2, varscan2
- NCKAP1L | c.2454G>T p.L818= | Silent (SNP) | VAF 148/307 reads (48%) | catalogued as rs1363462352; called by muse, mutect2, varscan2
- NLGN4Y | c.918C>T p.C306= | Silent (SNP) | VAF 227/287 reads (79%) | called by muse, mutect2, varscan2
- OR10AG1 | c.405G>T p.L135= | Silent (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- OR2C3 | c.444C>A p.A148= | Silent (SNP) | VAF 177/416 reads (43%) | catalogued as COSV63576061; called by muse, mutect2, varscan2
- OR2T27 | c.216G>A p.L72= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as COSV61281175; called by muse, mutect2, varscan2
- P2RX3 | c.642C>T p.P214= | Silent (SNP) | VAF 78/415 reads (19%) | catalogued as COSV99628919; called by muse, mutect2, varscan2
- PCDHB4 | c.828T>A p.V276= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- PLA2R1 | c.765G>A p.E255= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV51784119; called by muse, mutect2, varscan2
- PNPLA6 | c.216G>T p.T72= (on ENST00000414982 / NM_001166111.2; = p.T24= on NM_006702.5) | Silent (SNP) | VAF 80/232 reads (34%) | catalogued as rs550795683; called by muse, mutect2
- POC5 | c.639A>G p.E213= (on ENST00000428202 / NM_001099271.2; = p.E188= on NM_152408.2) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1263261449; called by muse, mutect2, varscan2
- PXDNL | c.1173G>A p.R391= | Silent (SNP) | VAF 71/315 reads (23%) | catalogued as COSV100684252; called by muse, mutect2, varscan2
- RNF213 | c.10884C>T p.V3628= | Silent (SNP) | VAF 39/340 reads (11%) | called by muse, mutect2, varscan2
- SLC14A2 | c.1111C>T p.L371= | Silent (SNP) | VAF 87/214 reads (41%) | called by muse, mutect2, varscan2
- SNTA1 | c.244C>T p.L82= | Silent (SNP) | VAF 65/186 reads (35%) | called by muse, mutect2, varscan2
- SOBP | c.2199G>A p.E733= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs952441006; called by mutect2, varscan2
- SREBF2 | c.1251G>T p.V417= | Silent (SNP) | VAF 130/408 reads (32%) | called by mutect2, varscan2
- STXBP2 | c.1479G>A p.R493= | Silent (SNP) | VAF 134/396 reads (34%) | called by muse, mutect2, varscan2
- SYNE1 | c.16221A>G p.L5407= (on ENST00000367255 / NM_182961.4; = p.L5336= on NM_033071.3) | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- TAF7 | c.852G>A p.Q284= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- TBX5 | c.1011C>A p.P337= | Silent (SNP) | VAF 84/341 reads (25%) | called by muse, mutect2, varscan2
- TMEM132C | c.1248C>A p.A416= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as rs900002247, COSV59432890; called by muse, mutect2, varscan2
- TPP2 | c.1905A>T p.I635= | Silent (SNP) | VAF 65/95 reads (68%) | called by muse, mutect2, varscan2
- TRIM67 | c.861G>C p.A287= | Silent (SNP) | VAF 103/188 reads (55%) | catalogued as rs768391397, COSV64159113; called by muse, mutect2, varscan2
- TTN | c.81429C>T p.P27143= (on ENST00000591111; = p.P19719= on NM_003319.4) | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- UQCRFS1 | c.39C>T p.P13= | Silent (SNP) | VAF 53/244 reads (22%) | catalogued as rs907234512; called by muse, mutect2, varscan2
- VCAN | c.93G>T p.P31= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV54105046; called by muse, mutect2, varscan2
- WDR6 | c.489C>T p.A163= | Silent (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- WT1 | c.117G>T p.R39= | Silent (SNP) | VAF 90/349 reads (26%) | called by muse, mutect2, varscan2
- ZNF532 | c.3519T>C p.V1173= | Silent (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- ZNF595 | c.903A>G p.E301= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as rs992070408; called by muse, mutect2, varscan2
- ZNF714 | c.72G>T p.P24= | Silent (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- AC011487.2 | n.1089C>A | RNA (SNP) | VAF 101/269 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.*73C>A | 3'UTR (SNP) | VAF 175/557 reads (31%) | catalogued as COSV52469446; called by muse, mutect2, varscan2
- ADK | c.-32C>T | 5'UTR (SNP) | VAF 72/226 reads (32%) | catalogued as rs548595704; called by muse, mutect2, varscan2
- AGFG2 | c.*7_*8del | 3'UTR (DEL) | VAF 69/326 reads (21%) | catalogued as rs762121621; called by pindel, varscan2
- AL391261.1 | n.89C>T | RNA (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- ANKRD17 | c.4401+517G>C | Intron (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- C5orf60 | n.1499C>T | RNA (SNP) | VAF 13/49 reads (27%) | called by muse, varscan2
- C8orf87 | n.317C>A | RNA (SNP) | VAF 173/360 reads (48%) | called by muse, mutect2, varscan2
- CENPC | c.2761+33A>G | Intron (SNP) | VAF 36/62 reads (58%) | catalogued as rs749186749; called by muse, mutect2, varscan2
- CISH | c.20+89G>T | Intron (SNP) | VAF 183/236 reads (78%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-1084G>T | Intron (SNP) | VAF 224/467 reads (48%) | called by muse, mutect2, varscan2
- CSH2 | c.456+40C>G | Intron (SNP) | VAF 219/554 reads (40%) | called by muse, mutect2, varscan2
- CXADRP2 | n.547C>A | RNA (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- DENND5A | c.1906+1245del | Intron (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- DISP2 | c.-28C>A | 5'UTR (SNP) | VAF 92/156 reads (59%) | catalogued as rs1023632770; called by muse, mutect2, varscan2
- EOMES | c.1380-13C>A | Intron (SNP) | VAF 57/78 reads (73%) | called by muse, mutect2, varscan2
- EYS | c.1767-7021C>T | Intron (SNP) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- FAM161A | c.*942T>G | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- FCGR2B | c.646+252G>A | Intron (SNP) | VAF 49/219 reads (22%) | catalogued as rs757049657; called by muse, mutect2, varscan2
- IQCK | c.475-2477G>C | Intron (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- ITIH5 | c.*3256T>C | 3'UTR (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- KCTD19 | c.-19C>G | 5'UTR (SNP) | VAF 66/154 reads (43%) | catalogued as rs200412656; called by muse, mutect2, varscan2
- LILRB5 | c.1630-86A>T | Intron (SNP) | VAF 146/434 reads (34%) | called by muse, varscan2
- LINC00967 | n.988A>T | RNA (SNP) | VAF 66/289 reads (23%) | called by muse, mutect2, varscan2
- LINC02740 | n.211C>G | RNA (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.*8C>A | 3'UTR (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- MUC1 | c.-7C>A | 5'UTR (SNP) | VAF 42/410 reads (10%) | called by muse, mutect2, varscan2
- OR51A7 | c.*17G>T | 3'UTR (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- PCNX2 | c.3838-17100G>A | Intron (SNP) | VAF 22/96 reads (23%) | catalogued as rs1226186021; called by muse, mutect2, varscan2
- PLEKHO1 | c.424-49G>T | Intron (SNP) | VAF 150/241 reads (62%) | called by muse, mutect2, varscan2
- POP1 | c.*37G>T | 3'UTR (SNP) | VAF 65/126 reads (52%) | catalogued as COSV100856133; called by muse, mutect2, varscan2
- RGL2 | c.241-97A>G | Intron (SNP) | VAF 90/196 reads (46%) | called by muse, mutect2, varscan2
- RPN2 | c.*41G>A | 3'UTR (SNP) | VAF 98/246 reads (40%) | called by muse, mutect2
- SHLD2 | chr10:87094301 G>A | 5'Flank (SNP) | VAF 69/195 reads (35%) | called by muse, mutect2, varscan2
- SNORD115-4 | n.72C>T | RNA (SNP) | VAF 108/270 reads (40%) | catalogued as rs111366147; called by muse, mutect2, varscan2
- SNORD115-48 | n.70G>A | RNA (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- SP100 | c.586+169C>T | Intron (SNP) | VAF 82/287 reads (29%) | called by muse, mutect2, varscan2
- SYBU | chr8:109645293 G>A | 5'Flank (SNP) | VAF 139/328 reads (42%) | called by muse, mutect2, varscan2
- SYBU | chr8:109645294 C>T | 5'Flank (SNP) | VAF 141/329 reads (43%) | called by muse, mutect2, varscan2
- TMEM135 | c.*5388A>T | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- TUBB7P | n.348G>T | RNA (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.965G>T | RNA (SNP) | VAF 224/1322 reads (17%) | catalogued as rs1323816605; called by muse, varscan2
- TWIST1 | c.-40C>A | 5'UTR (SNP) | VAF 104/351 reads (30%) | called by muse, mutect2
- ZNF232 | c.-23G>T | 5'UTR (SNP) | VAF 114/180 reads (63%) | called by muse, mutect2, varscan2
- ZNF606 | c.-131C>A | 5'UTR (SNP) | VAF 61/168 reads (36%) | called by muse, mutect2, varscan2
